CCDI case PBCESI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/05ba5e9b-1cb4-4f87-b294-c5481c2068d7

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.5 years (917 days).

Biospecimens (3 samples)
- Sample 0DQB23: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DQB2L: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DQB2V: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
